CPTAC case C3N-03086 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8df42d8-58bc-4c43-b18b-5b23f5e61508

Demographics
Sex at birth: male; Race: asian; Year of birth: 1948; Vital status: Dead; Days to death: 760 days (2.1 years); Year of death: 2020; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 69.8 years (25,502 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 760 days (2.1 years); Progression or recurrence: no; Days to last follow up: 733 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 22; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 353 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 733 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 733 days (2.0 years); Disease response: Partial Response; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 733 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 56 kg; Height: 165 cm; BMI: 20.57.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03086-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 456 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03086-22: Section location: Body; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3N-03086-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 348 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03086-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
